Somatic mutation profile of tumor specimen TCGA-30-1714-01A (aliquot TCGA-30-1714-01A-02W-0633-09) from TCGA case TCGA-30-1714, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 68.5 years (25,032 days).
Specimen TCGA-30-1714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5a1d480-c674-42b8-a8cf-3670e35e29fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1714-10A (Blood Derived Normal), aliquot TCGA-30-1714-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87520b17-4120-4afd-be94-603abe1d91ae

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 12, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 113/133 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.2077G>A p.D693N | Missense Mutation (SNP) | VAF 133/319 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.983); catalogued as rs781251434, COSV63976308, COSV63976810; called by muse, mutect2, varscan2
- AK9 | c.5429C>T p.T1810I | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV69849315; called by muse, mutect2, varscan2
- APPBP2 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 16/237 reads (7%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.481); catalogued as COSV99319869; called by muse, mutect2
- BARHL2 | c.674C>G p.P225R | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV64980860, COSV64980914; called by muse, mutect2, varscan2
- BRINP3 | c.2297G>A p.S766N | Missense Mutation (SNP) | VAF 21/277 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.227); catalogued as COSV100819385, COSV66516757; called by muse, mutect2
- BTBD3 | c.292A>T p.N98Y | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV99656133; called by muse, mutect2
- CCDC178 | c.1501G>C p.E501Q | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs1405361312, COSV55760974; called by muse, mutect2, varscan2
- CCDC93 | c.1026C>A p.S342R | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100099397; called by muse, mutect2, varscan2
- CCDC93 | c.1025G>C p.S342T | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100099402; called by muse, mutect2, varscan2
- CCR9 | c.735G>T p.K245N (on ENST00000357632 / NM_031200.3; = p.K233N on NM_006641.4) | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV62939870; called by muse, mutect2, varscan2
- CEP290 | c.6334C>T p.R2112W | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1370883149, COSV58349175; called by muse, mutect2, varscan2
- CEP70 | c.1733-1G>A p.X578_splice | Splice Site (SNP) | VAF 12/56 reads (21%) | catalogued as COSV53874416; called by muse, mutect2, varscan2
- CGN | c.1453C>T p.R485* | Nonsense Mutation (SNP) | VAF 6/61 reads (10%) | catalogued as rs1325924492, COSV99642769; called by muse, mutect2
- COL4A4 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61629856; called by muse, mutect2, varscan2
- COL6A3 | c.5224C>T p.R1742W | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs578249894, COSV55080759, COSV99797464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLGAP4 | c.2074G>A p.G692R (on ENST00000339266 / NM_001365621.1; = p.G153R on NM_183006.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as COSV59414806; called by muse, mutect2, varscan2
- DOK2 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52387722; called by muse, mutect2, varscan2
- DST | c.2282T>C p.I761T (on ENST00000361203 / NM_001374722.1; = p.I435T on NM_001723.6) | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54999703; called by muse, mutect2, varscan2
- ELOVL2 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.767); catalogued as rs554486961, COSV61154096; called by muse, mutect2, varscan2
- ENTPD6 | c.1137C>G p.F379L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV100737173; called by muse, mutect2
- FHOD3 | c.1754C>A p.A585D (on ENST00000359247 / NM_001281739.3; = p.A602D on NM_025135.5) | Missense Mutation (SNP) | VAF 65/111 reads (59%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.297); catalogued as COSV57165510; called by muse, mutect2, varscan2
- FIGN | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 216/471 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60763420; called by muse, mutect2, varscan2
- GATM | c.734T>C p.V245A | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV67540182; called by muse, mutect2, varscan2
- GJB4 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148686980; called by muse, mutect2, varscan2
- IGSF21 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.401); catalogued as rs779760361, COSV52126192; called by muse, mutect2, varscan2
- KIF21B | c.3737C>T p.P1246L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as COSV59752918; called by muse, mutect2, varscan2
- LPA | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs766070403, COSV60297598; called by muse, mutect2, varscan2
- MROH7 | c.2207G>T p.R736L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV59868491; called by muse, mutect2, varscan2
- NAV1 | c.4039-2A>C p.X1347_splice | Splice Site (SNP) | VAF 59/330 reads (18%) | catalogued as COSV55214412; called by muse, mutect2, varscan2
- NCKAP1L | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.538); catalogued as COSV53203520, COSV53213107; called by muse, mutect2, varscan2
- NEK11 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 46/210 reads (22%) | catalogued as rs773314504, COSV53907680; called by muse, mutect2, varscan2
- NF1 | c.1399dup p.T467Nfs*3 | Frame Shift Ins (INS) | VAF 19/40 reads (48%) | catalogued as rs778963145, CI031910; called by mutect2, pindel, varscan2
- NRXN2 | c.2008C>A p.L670I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs576418675, COSV55447963; called by muse, mutect2, varscan2
- OR51B6 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.052); catalogued as rs775043301, COSV66512327; called by muse, mutect2, varscan2
- PDS5B | c.3889C>G p.L1297V | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.019); catalogued as COSV59723836, COSV59734515; called by muse, mutect2, varscan2
- PIK3C3 | c.2128A>G p.S710G | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.297); catalogued as COSV56276213; called by muse, mutect2, varscan2
- PLA2G4C | c.1531G>A p.V511I | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.802); catalogued as rs1250751163, COSV62784080; called by muse, mutect2, varscan2
- POP5 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100378966; called by muse, mutect2
- RYR1 | c.5979A>T p.R1993S | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV62090104; called by muse, mutect2, varscan2
- SLC15A1 | c.945+1G>A p.X315_splice | Splice Site (SNP) | VAF 155/392 reads (40%) | catalogued as rs906718093, COSV64730164; called by muse, mutect2, varscan2
- SLC43A3 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV61449859, COSV61451231; called by muse, mutect2, varscan2
- SLC5A8 | c.1493C>G p.T498S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV73310385; called by muse, mutect2, varscan2
- TBRG4 | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV51831887; called by muse, mutect2, varscan2
- TBX15 | c.1364C>T p.S455L (on ENST00000369429 / NM_001330677.2; = p.S349L on NM_152380.3) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.736); catalogued as rs141953431; called by muse, mutect2, varscan2
- TCEAL4 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 128/325 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV65463093; called by muse, mutect2, varscan2
- TPTE | c.514G>T p.V172F (on ENST00000618007 / NM_199261.4; = p.V154F on NM_199259.4) | Missense Mutation (SNP) | VAF 54/453 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.583); catalogued as rs773134113; called by muse, mutect2, varscan2
- TSPYL1 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV63993941; called by muse, mutect2, varscan2
- UBE2O | c.1943A>C p.H648P | Missense Mutation (SNP) | VAF 66/245 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60060508, COSV60063650; called by muse, mutect2, varscan2
- WDR91 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV60368690; called by muse, mutect2, varscan2
- ZNF366 | c.1878C>A p.Y626* | Nonsense Mutation (SNP) | VAF 16/77 reads (21%) | catalogued as COSV59213955, COSV59218228; called by muse, mutect2, varscan2
- B4GALT5 | c.209_215del p.R70Lfs*9 | Frame Shift Del (DEL) | VAF 64/334 reads (19%) | called by mutect2, pindel, varscan2
- CELSR2 | c.1192dup p.Q398Pfs*3 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- CIC | c.2762del p.K921Rfs*3 | Frame Shift Del (DEL) | VAF 9/77 reads (12%) | called by mutect2, pindel, varscan2
- EVL | c.347_349del p.E116del (on ENST00000402714 / NM_001330221.2; = p.E118del on NM_016337.3) | In Frame Del (DEL) | VAF 19/126 reads (15%) | called by pindel, varscan2
- KDM6A | c.2858_2859del p.F953Sfs*25 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | called by mutect2, pindel, varscan2
- TOR1AIP2 | c.978_979del p.P327Hfs*4 | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | called by pindel, varscan2
- ABCA13 | c.6294T>G p.T2098= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV70026053; called by muse, mutect2, varscan2
- ABCC11 | c.210C>T p.T70= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV62321525; called by muse, mutect2, varscan2
- ATP6V0A4 | c.2265T>A p.S755= | Silent (SNP) | VAF 13/384 reads (3%) | catalogued as COSV100023623; called by muse, mutect2
- C9orf72 | c.1170C>T p.G390= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV66163302; called by muse, mutect2, varscan2
- FAM71A | c.132G>A p.P44= | Silent (SNP) | VAF 65/309 reads (21%) | catalogued as rs751300602, COSV54234699; called by muse, mutect2, varscan2
- MAG | c.1179G>T p.V393= | Silent (SNP) | VAF 5/139 reads (4%) | called by muse, mutect2
- MAST1 | c.351C>T p.R117= | Silent (SNP) | VAF 83/123 reads (67%) | catalogued as COSV52241585; called by muse, mutect2, varscan2
- NEXMIF | c.4032C>A p.P1344= | Silent (SNP) | VAF 90/216 reads (42%) | catalogued as COSV50022437; called by muse, mutect2, varscan2
- OTX1 | c.549G>C p.S183= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56993742; called by muse, mutect2, varscan2
- RASA1 | c.2808T>G p.S936= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs754906693, COSV57191761; called by muse, mutect2, varscan2
- TIPARP | c.18C>T p.T6= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs190841318, COSV55813335; called by muse, mutect2, varscan2
- TRIM4 | c.1389G>T p.V463= | Silent (SNP) | VAF 26/695 reads (4%) | catalogued as COSV100584247, COSV100584402; called by muse, mutect2
- RAB4A | c.*1492A>C | 3'UTR (SNP) | VAF 39/191 reads (20%) | catalogued as COSV64206933; called by muse, mutect2, varscan2
